CCDI case PBBXHT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS.
https://portal.gdc.cancer.gov/cases/d68891e1-7033-4ea1-a7e6-8593d088521c

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 4.4 years (1,589 days).

Biospecimens (3 samples)
- Sample 0DJTFN: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DJTFV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DJTG1: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
